Somatic mutation profile of tumor specimen TCGA-68-7756-01A (aliquot TCGA-68-7756-01A-11D-2122-08) from TCGA case TCGA-68-7756, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 84.2 years (30,763 days).
Specimen TCGA-68-7756-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 008b0cca-f90e-4fdb-9840-085ec00d52cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-7756-10A (Blood Derived Normal), aliquot TCGA-68-7756-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0faa0dfd-ac6a-43a6-990d-ab3190b387ad

The open-access MAF lists 119 somatic variants for this specimen: 92 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 21, In Frame Del 8, Frame Shift Del 7, Nonsense Mutation 4, Intron 3, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2, varscan2
- ABCC12 | c.1995A>T p.L665F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100252873; called by mutect2, varscan2
- ADAMTS18 | c.3035G>T p.R1012M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV99270800; called by muse, mutect2, varscan2
- AKAP4 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs1557204598, COSV100654305; called by muse, mutect2, varscan2
- AMPH | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.314); catalogued as rs1354574545, COSV100342636, COSV57759702; called by muse, mutect2, varscan2
- ANKRD13C | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.845); catalogued as rs1382344920, COSV99257194; called by muse, mutect2, varscan2
- ATG14 | c.1425_1427del p.S476del | In Frame Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs1200241736; called by pindel, varscan2
- BCAR3 | c.1724_1726del p.R575del | In Frame Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs764367470; called by pindel, varscan2
- BCHE | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012743, COSV52257243; called by muse, mutect2, varscan2
- BNC1 | c.2611C>A p.H871N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100597289; called by muse, mutect2, varscan2
- BRINP1 | c.1718A>T p.E573V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99776022; called by muse, mutect2, varscan2
- CARNS1 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV100322100; called by muse, mutect2
- CD109 | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV99753921; called by muse, mutect2, varscan2
- CLCA2 | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991400; called by muse, mutect2, varscan2
- CNNM4 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65660182; called by muse, mutect2, varscan2
- CSMD3 | c.11024C>A p.A3675E (on ENST00000297405 / NM_001363185.1; = p.A3506E on NM_052900.3) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757642380, COSV99838317; called by muse, mutect2, varscan2
- CSMD3 | c.6727G>T p.G2243C (on ENST00000297405 / NM_001363185.1; = p.G2139C on NM_052900.3) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52120955; called by muse, mutect2, varscan2
- DAAM2 | c.3079G>C p.V1027L (on ENST00000274867 / NM_001201427.2; = p.V1026L on NM_015345.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99226126; called by muse, mutect2
- DDX19A | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100156332; called by muse, mutect2
- DNAJC14 | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1465739474, COSV100423646; called by muse, mutect2, varscan2
- DPPA3 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100559941, COSV100560065; called by muse, mutect2, varscan2
- FAM171A1 | c.2400A>T p.E800D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100968336; called by muse, mutect2
- GJA10 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101005381; called by muse, mutect2, varscan2
- GRIN3A | c.1580T>C p.F527S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100701609; called by muse, mutect2, varscan2
- GSTCD | c.270G>C p.L90F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100853856; called by muse, mutect2, varscan2
- HMCN1 | c.12263A>G p.Y4088C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99631244; called by muse, mutect2, varscan2
- IGLV8-61 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.386); catalogued as COSV101135147; called by muse, mutect2, varscan2
- IL12A | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99975801; called by muse, mutect2
- IL1RL1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294237; called by muse, mutect2
- ITGA7 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99147342; called by muse, mutect2, varscan2
- KLHL34 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs778535378, COSV65278702, COSV65279875; called by muse, mutect2
- KMT2E | c.2881_2882del p.K961Efs*5 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as rs777413129; called by mutect2, pindel, varscan2
- MERTK | c.2573T>A p.L858* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99774849; called by muse, mutect2, varscan2
- MMP9 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.361); catalogued as rs200619019, COSV100812426; called by muse, mutect2, varscan2
- MYO15A | c.4399T>C p.F1467L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV99233383; called by muse, mutect2, varscan2
- NKD2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.368); catalogued as COSV99723795; called by muse, mutect2, varscan2
- NOL4 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV52361472, COSV99307795; called by muse, mutect2
- NSMCE1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs549268272, COSV100814999; called by muse, mutect2, varscan2
- NTN5 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99539469; called by muse, mutect2, varscan2
- OLIG3 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); catalogued as COSV62988697; called by muse, mutect2, varscan2
- OR14I1 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100700498; called by muse, mutect2, varscan2
- OR2L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs138166879; called by muse, mutect2, varscan2
- OR4C11 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100155377; called by muse, mutect2, varscan2
- OR52I1 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331751; called by muse, mutect2, varscan2
- OR6F1 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV100129282, COSV57468140; called by muse, mutect2, varscan2
- OR8B8 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV60145116; called by muse, mutect2, varscan2
- PANX3 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99421603; called by muse, mutect2, varscan2
- PCDHGA6 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as rs371650654, COSV99541268; called by muse, mutect2, varscan2
- PLD1 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs755231943, COSV100578393; called by muse, mutect2, varscan2
- PPP1R26 | c.1646G>C p.G549A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV100778099; called by muse, mutect2, varscan2
- PRND | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as rs747210588, COSV59897187; called by muse, mutect2, varscan2
- RFPL2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV99964366; called by muse, mutect2, varscan2
- RGS22 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62665585; called by muse, mutect2
- RIOK2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99300062; called by muse, mutect2, varscan2
- RNF122 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99823155; called by muse, mutect2, varscan2
- RYR2 | c.13885C>T p.Q4629* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100771401; called by muse, mutect2
- SETX | c.4445_4447del p.E1482del | In Frame Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs780884686; called by pindel, varscan2
- SLC24A2 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646895; called by muse, mutect2, varscan2
- SLC41A3 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757711644, COSV100259678; called by muse, mutect2, varscan2
- SLC6A3 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV54366080, COSV99548557; called by muse, mutect2, varscan2
- SPACA4 | c.268T>G p.C90G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614140; called by muse, mutect2
- STEAP3 | c.979C>G p.R327G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.349); catalogued as COSV100713360, COSV61530371; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2812T>C p.C938R | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100561983; called by muse, mutect2, varscan2
- TCHH | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 13/147 reads (9%) | catalogued as COSV100915213; called by muse, mutect2
- TEPSIN | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530546424, COSV100329766; called by muse, varscan2
- TMEM41A | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99956629; called by muse, mutect2
- TNFRSF19 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99947490; called by muse, mutect2, varscan2
- TRIM10 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64998139; called by muse, mutect2, varscan2
- TRPM3 | c.886C>G p.L296V (on ENST00000357533 / NM_001366142.2; = p.L141V on NM_020952.6) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1254159634, COSV100625028; called by muse, mutect2, varscan2
- UACA | c.3917_3919del p.R1306del | In Frame Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs1566962581; called by pindel, varscan2
- UBASH3B | c.777A>T p.L259F | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99418140; called by muse, mutect2, varscan2
- UBN2 | c.3652G>T p.V1218L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.414); catalogued as rs770676500, COSV99944138; called by muse, mutect2, varscan2
- UMPS | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377750200; called by muse, mutect2, varscan2
- UMPS | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201332523; called by muse, mutect2, varscan2
- WDR72 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs761647336, COSV64752661, COSV64752935; called by muse, mutect2, varscan2
- WRN | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99989332; called by muse, mutect2, varscan2
- ZAN | c.3177C>G p.C1059W | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100769880; called by muse, mutect2, varscan2
- ZBBX | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100284357; called by muse, mutect2, varscan2
- ZNF175 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV99219590; called by muse, mutect2, varscan2
- ZNF43 | c.1930C>G p.H644D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100731859; called by muse, mutect2
- ZNF644 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as COSV100494553; called by muse, mutect2, varscan2
- ZNF878 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.079); catalogued as COSV101521202; called by muse, mutect2, varscan2
- AGTR1 | c.1080del p.*360Cfs*8 | Frame Shift Del (DEL) | VAF 19/151 reads (13%) | called by mutect2, pindel, varscan2
- C9orf131 | c.1722_1723del p.R574Sfs*2 | Frame Shift Del (DEL) | VAF 36/212 reads (17%) | called by pindel, varscan2
- EDIL3 | c.1285_1289del p.K429* | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by pindel, varscan2
- F5 | c.1291_1294del p.L431Kfs*19 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- MYH11 | c.3262_3264del p.K1088del | In Frame Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- PRDM15 | c.2554_2556del p.K852del | In Frame Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- RASA1 | c.1220_1223del p.N407Sfs*3 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- RSPH4A | c.1261_1263del p.E421del | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- STAG2 | c.2152del p.T718Lfs*23 | Frame Shift Del (DEL) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.871_873del p.K291del | In Frame Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.2061T>A p.T687= (on ENST00000611781; = p.T631= on NM_052997.2) | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100653821, COSV100654160; called by muse, mutect2
- ANO8 | c.888G>T p.T296= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV50176389, COSV99344627; called by muse, mutect2, varscan2
- ASPHD2 | c.297C>T p.N99= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1053734918, COSV99313437; called by muse, mutect2, varscan2
- ASXL1 | c.2805C>T p.P935= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100037857, COSV100039941; called by muse, mutect2, varscan2
- ATP6V0A4 | c.522C>T p.A174= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs563386735, COSV100023260, COSV59477334; called by muse, mutect2, varscan2
- C2orf16 | c.5167C>A p.R1723= | Silent (SNP) | VAF 87/310 reads (28%) | catalogued as COSV100820857, COSV62673981; called by muse, mutect2, varscan2
- CCDC63 | c.666G>A p.E222= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV100370451; called by muse, mutect2, varscan2
- CDH12 | c.1968C>T p.N656= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs779545047, COSV101202499, COSV66411353; called by muse, mutect2, varscan2
- CSMD3 | c.4164C>T p.H1388= (on ENST00000297405 / NM_001363185.1; = p.H1284= on NM_052900.3) | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs140111920; called by muse, mutect2, varscan2
- IGKV1D-42 | c.237G>T p.G79= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- MLH1 | c.990C>T p.I330= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs372578171, CD117415; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTOR | c.7413G>C p.T2471= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100816359; called by muse, mutect2, varscan2
- PCDHA8 | c.1317C>A p.A439= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV100970835; called by muse, mutect2, varscan2
- RETNLB | c.249T>A p.G83= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99848827; called by muse, mutect2, varscan2
- RNFT2 | c.873C>G p.V291= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99985378; called by muse, mutect2
- SNRPB2 | c.132G>A p.K44= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99855879; called by muse, mutect2, varscan2
- SPATA31E1 | c.1206C>A p.T402= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100350652; called by muse, mutect2, varscan2
- TMEM132A | c.825C>A p.L275= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99135873; called by muse, mutect2, varscan2
- VPS13D | c.1488T>C p.F496= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100693255; called by muse, mutect2, varscan2
- ZBTB11 | c.2976T>A p.T992= | Silent (SNP) | VAF 37/201 reads (18%) | catalogued as COSV100465571; called by muse, mutect2, varscan2
- ZNF570 | c.1557T>A p.I519= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as COSV100356233; called by muse, mutect2
- AL353804.4 | chrX:73823055 del T | 5'Flank (DEL) | VAF 6/24 reads (25%) | catalogued as rs755255238; called by mutect2, varscan2
- ATXN2L | c.*112G>T | 3'UTR (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100294636; called by muse, mutect2, varscan2
- MAG | c.1716+268_1716+269del | Intron (DEL) | VAF 31/144 reads (22%) | called by mutect2, pindel, varscan2
- PTGER3 | c.1077+44G>T | Intron (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100139164; called by muse, mutect2, varscan2
- PTGER3 | c.1077+43G>T | Intron (SNP) | VAF 17/93 reads (18%) | catalogued as COSV60688830; called by muse, mutect2, varscan2
- SNORD115-40 | n.48T>G | RNA (SNP) | VAF 98/418 reads (23%) | catalogued as rs1164197495; called by muse, mutect2
